Somatic mutation profile of tumor specimen TARGET-20-PASRIN-09A (aliquot TARGET-20-PASRIN-09A-01D) from TARGET case TARGET-20-PASRIN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (4,994 days).
Specimen TARGET-20-PASRIN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec47291b-3861-4b5d-b895-a1400241f4d4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASRIN-14A (Bone Marrow Normal), aliquot TARGET-20-PASRIN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea810e7-6abf-488a-bd47-b5a805e2bcd0

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/151 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as CM971595, COSV60065297; called by muse, mutect2, varscan2
- TIAM1 | c.*1907del | 3'UTR (DEL) | VAF 27/162 reads (17%) | catalogued as COSV99734313; called by mutect2, pindel, varscan2
